Somatic mutation profile of tumor specimen ALCH-AEU9-TTP1-A (aliquot ALCH-AEU9-TTP1-A-1-0-D-A657-36) from ALCHEMIST case ALCH-AEU9, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 50.8 years (18,557 days).
Specimen ALCH-AEU9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b469f0b-f111-4c6b-9097-f1b778c8afb8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AEU9-NB1-A (Blood Derived Normal), aliquot ALCH-AEU9-NB1-A-1-0-D-A658-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e85cfd2e-eebf-4eb2-b36c-e367e1b381df

The open-access MAF lists 606 somatic variants for this specimen: 422 protein-altering or splice-affecting, 111 silent, 73 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 360, Silent 111, Intron 34, Nonsense Mutation 31, RNA 14, 5'UTR 11, Frame Shift Del 8, 3'UTR 8, Splice Site 7, Frame Shift Ins 7, 5'Flank 5, Splice Region 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.580G>T p.D194Y | Missense Mutation (SNP) | VAF 41/66 reads (62%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913315, CM991156, COSV58820621, COSV58820976, COSV99045288; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 326/554 reads (59%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACKR1 | c.1007C>A p.S336Y | Missense Mutation (SNP) | VAF 30/90 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV63672543; called by muse, mutect2, varscan2
- ACSS3 | c.1867G>A p.V623I | Missense Mutation (SNP) | VAF 121/348 reads (35%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as rs745644861; called by muse, mutect2, varscan2
- ACTRT1 | c.492C>A p.C164* | Nonsense Mutation (SNP) | VAF 91/146 reads (62%) | catalogued as COSV100947717; called by muse, mutect2, varscan2
- AHNAK2 | c.7261A>C p.I2421L | Missense Mutation (SNP) | VAF 83/328 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs759529710; called by muse, mutect2, varscan2
- AIDA | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.969); catalogued as rs111707998; called by muse, mutect2, varscan2
- ANKRD13A | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 167/572 reads (29%) | catalogued as rs768945364; called by muse, mutect2, varscan2
- ANKRD36C | c.4226G>A p.R1409K | Missense Mutation (SNP) | VAF 123/758 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV101337293; called by muse, mutect2, varscan2
- ANO3 | c.2364G>T p.R788S | Missense Mutation (SNP) | VAF 228/599 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs777119897; called by muse, mutect2, varscan2
- ATP7B | c.461G>T p.C154F | Missense Mutation (SNP) | VAF 74/133 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99667126; called by muse, mutect2, varscan2
- BRINP3 | c.907C>A p.L303I | Missense Mutation (SNP) | VAF 95/257 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV66518815, COSV66530171; called by muse, mutect2, varscan2
- C14orf28 | c.254del p.G85Vfs*5 | Frame Shift Del (DEL) | VAF 154/489 reads (31%) | catalogued as COSV100290299; called by mutect2, pindel, varscan2
- C7 | c.1217G>T p.W406L | Missense Mutation (SNP) | VAF 105/255 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100495953; called by muse, mutect2, varscan2
- CCDC3 | c.707G>C p.R236P | Missense Mutation (SNP) | VAF 126/313 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV66558633; called by muse, mutect2, varscan2
- CDH19 | c.127C>A p.R43S | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs780796077, COSV50954307; called by muse, mutect2, varscan2
- CENPC | c.1073T>C p.L358S | Missense Mutation (SNP) | VAF 294/522 reads (56%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as rs1355364195; called by muse, mutect2, varscan2
- CEP250 | c.6919C>T p.R2307W | Missense Mutation (SNP) | VAF 59/363 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.8); catalogued as rs915467191; called by muse, mutect2, varscan2
- CFAP47 | c.2763G>T p.Q921H | Missense Mutation (SNP) | VAF 132/195 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.353); catalogued as COSV52892823; called by muse, mutect2, varscan2
- CHL1 | c.217G>T p.G73C | Missense Mutation (SNP) | VAF 77/180 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56603313; called by muse, mutect2, varscan2
- CHRNA7 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 115/262 reads (44%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.839); catalogued as rs372054567; called by muse, mutect2, varscan2
- CNTNAP3 | c.2908C>T p.R970C | Missense Mutation (SNP) | VAF 63/698 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs546554958, COSV52675068; called by muse, mutect2, varscan2
- COL19A1 | c.2180G>C p.R727P | Missense Mutation (SNP) | VAF 67/316 reads (21%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.536); catalogued as COSV100506942, COSV59583348; called by muse, mutect2, varscan2
- COL22A1 | c.4628C>A p.A1543D | Missense Mutation (SNP) | VAF 39/139 reads (28%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.617); catalogued as rs1232267310, COSV100279232; called by muse, mutect2, varscan2
- CSMD3 | c.10793G>T p.G3598V (on ENST00000297405 / NM_001363185.1; = p.G3429V on NM_052900.3) | Missense Mutation (SNP) | VAF 360/920 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); catalogued as COSV52233001; called by muse, varscan2
- CTTN | c.313C>T p.Q105* | Nonsense Mutation (SNP) | VAF 93/182 reads (51%) | catalogued as COSV57236176; called by muse, mutect2, varscan2
- DAO | c.115T>A p.F39I | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57324046; called by muse, mutect2, varscan2
- DBR1 | c.779A>G p.H260R | Missense Mutation (SNP) | VAF 146/357 reads (41%) | SIFT tolerated (0.57); PolyPhen benign (0.012); catalogued as rs749857302; called by muse, mutect2, varscan2
- DCDC1 | c.2197G>A p.G733R | Missense Mutation (SNP) | VAF 104/300 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.399); catalogued as COSV60840126; called by muse, mutect2, varscan2
- DOCK1 | c.2490G>T p.M830I | Missense Mutation (SNP) | VAF 168/395 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV54732070; called by muse, mutect2, varscan2
- EBF3 | c.1357C>A p.Q453K (on ENST00000355311 / NM_001375392.1; = p.Q444K on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 230/464 reads (50%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.101); catalogued as rs1172303286, COSV62473685; called by muse, mutect2, varscan2
- EPHB1 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 25/91 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV101214027; called by muse, mutect2, varscan2
- EPHB6 | c.1567C>A p.Q523K | Missense Mutation (SNP) | VAF 129/444 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100844259; called by muse, mutect2, varscan2
- ERCC6 | c.26C>A p.S9* | Nonsense Mutation (SNP) | VAF 259/678 reads (38%) | catalogued as COSV100875805; called by muse, mutect2, varscan2
- ERICH3 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 101/374 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as COSV58619297; called by muse, mutect2, varscan2
- EXOC4 | c.1400G>C p.R467P | Missense Mutation (SNP) | VAF 195/611 reads (32%) | SIFT tolerated (0.29); PolyPhen benign (0.324); catalogued as COSV54096338; called by muse, mutect2, varscan2
- FAM167A | c.584C>T p.P195L | Missense Mutation (SNP) | VAF 213/550 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.307); catalogued as rs940760420; called by muse, mutect2, varscan2
- FANCM | c.809G>T p.R270L | Missense Mutation (SNP) | VAF 287/851 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.945); catalogued as rs759079934, COSV57500323; called by mutect2, varscan2
- FAT1 | c.9158G>T p.R3053L | Missense Mutation (SNP) | VAF 120/216 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs756123882, COSV101499093; called by muse, mutect2, varscan2
- FRG2B | c.433C>T p.H145Y | Missense Mutation (SNP) | VAF 58/784 reads (7%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV101423524; called by muse, mutect2
- FSCB | c.71G>T p.S24I | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.155); catalogued as COSV100469019; called by muse, mutect2, varscan2
- GLI2 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 75/415 reads (18%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.509); catalogued as rs574656730, CM142413, COSV58043396; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLIPR2 | c.337A>T p.K113* | Nonsense Mutation (SNP) | VAF 65/211 reads (31%) | catalogued as COSV100936899; called by muse, mutect2, varscan2
- GPR158 | c.2467C>A p.H823N | Missense Mutation (SNP) | VAF 245/721 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as rs770714176; called by muse, mutect2, varscan2
- GRM5 | c.98G>T p.G33V | Missense Mutation (SNP) | VAF 265/658 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100554249, COSV59608505; called by muse, mutect2, varscan2
- GUCY1A2 | c.793G>C p.D265H | Missense Mutation (SNP) | VAF 218/627 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.5); catalogued as COSV56504112; called by muse, mutect2, varscan2
- H2BC4 | c.52G>T p.A18S | Missense Mutation (SNP) | VAF 36/228 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as rs777203378; called by muse, varscan2
- HCRTR1 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 48/283 reads (17%) | SIFT tolerated (0.69); PolyPhen benign (0.069); catalogued as rs199920679, COSV65484330; called by muse, mutect2, varscan2
- IGF2 | c.385C>G p.R129G (on ENST00000434045 / NM_001127598.3; = p.R73G on NM_000612.6) | Missense Mutation (SNP) | VAF 52/230 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.452); catalogued as COSV56096947, COSV56099500; called by muse, mutect2, varscan2
- IGHV3-11 | c.54G>C p.Q18H | Missense Mutation (SNP) | VAF 157/402 reads (39%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.417); catalogued as rs573226701; called by muse, mutect2, varscan2
- IGSF21 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 37/206 reads (18%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.988); catalogued as rs1266783855, COSV52141891; called by muse, mutect2, varscan2
- IL1R2 | c.661A>G p.T221A | Missense Mutation (SNP) | VAF 61/230 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.16); catalogued as rs139319473; called by muse, mutect2, varscan2
- ILDR2 | c.174C>G p.F58L | Missense Mutation (SNP) | VAF 120/438 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV99614066; called by muse, mutect2, varscan2
- IRF2 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 107/212 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101165921, COSV66928605; called by muse, mutect2, varscan2
- ITFG1 | c.1099G>T p.V367F | Missense Mutation (SNP) | VAF 73/342 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1295583212, COSV100279461; called by muse, mutect2, varscan2
- KIF5A | c.1468G>C p.A490P | Missense Mutation (SNP) | VAF 240/729 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99673425; called by muse, mutect2, varscan2
- KLHL14 | c.1321G>A p.V441M | Missense Mutation (SNP) | VAF 88/351 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs755190504; called by muse, mutect2, varscan2
- LRP1B | c.476G>A p.C159Y | Missense Mutation (SNP) | VAF 102/477 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101250474; called by muse, mutect2, varscan2
- LRRIQ3 | c.67A>G p.I23V | Missense Mutation (SNP) | VAF 103/276 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs774292822; called by muse, mutect2, varscan2
- LRRK2 | c.5023G>T p.D1675Y | Missense Mutation (SNP) | VAF 136/473 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.347); catalogued as COSV54162303; called by muse, mutect2, varscan2
- MAGI3 | c.2035G>T p.A679S | Missense Mutation (SNP) | VAF 87/240 reads (36%) | SIFT tolerated (0.66); PolyPhen benign (0.156); catalogued as rs766744419; called by muse, mutect2, varscan2
- MEX3C | c.1715G>T p.G572V | Missense Mutation (SNP) | VAF 76/311 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV68530315; called by muse, mutect2, varscan2
- MNDA | c.386G>A p.R129K | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV63741611; called by muse, mutect2, varscan2
- MROH9 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV63009617; called by muse, mutect2, varscan2
- NETO1 | c.85A>T p.K29* | Nonsense Mutation (SNP) | VAF 46/156 reads (29%) | catalogued as rs752366074; called by mutect2, varscan2
- NTNG1 | c.44C>G p.T15R | Missense Mutation (SNP) | VAF 150/441 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV53962028; called by muse, mutect2, varscan2
- NTRK3 | c.2445G>T p.L815F (on ENST00000360948 / NM_001012338.2; = p.L801F on NM_002530.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 203/610 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as COSV62304998; called by muse, mutect2, varscan2
- OR2T3 | c.542G>T p.S181I | Missense Mutation (SNP) | VAF 119/504 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.094); catalogued as COSV62082899; called by muse, mutect2, varscan2
- OR2T35 | c.616_621del p.M206_L207del | In Frame Del (DEL) | VAF 218/952 reads (23%) | catalogued as rs772046227; called by mutect2, pindel, varscan2
- OR4K14 | c.339G>T p.M113I | Missense Mutation (SNP) | VAF 184/522 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV59294150; called by muse, mutect2, varscan2
- OR51G1 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 206/845 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100429132, COSV100429202; called by muse, mutect2, varscan2
- OR52A1 | c.648C>A p.F216L | Missense Mutation (SNP) | VAF 233/560 reads (42%) | SIFT tolerated (0.4); PolyPhen benign (0.019); catalogued as rs866466696, COSV61092468; called by muse, mutect2, varscan2
- OR52J3 | c.253G>C p.G85R | Missense Mutation (SNP) | VAF 289/758 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV66747639; called by muse, mutect2, varscan2
- OR7D4 | c.605C>A p.A202D | Missense Mutation (SNP) | VAF 197/413 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.616); catalogued as COSV58072916; called by muse, mutect2, varscan2
- PCDHGA9 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 188/289 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.94); catalogued as COSV99535221; called by muse, mutect2, varscan2
- PCSK4 | c.2185A>G p.M729V | Missense Mutation (SNP) | VAF 9/13 reads (69%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs369872309; called by muse, mutect2, varscan2
- PLEKHG2 | c.3383C>T p.P1128L | Missense Mutation (SNP) | VAF 144/225 reads (64%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs772686056; called by muse, mutect2, varscan2
- PLSCR5 | c.113G>A p.W38* | Nonsense Mutation (SNP) | VAF 91/421 reads (22%) | catalogued as rs374073599; called by muse, mutect2, varscan2
- PPP3CA | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 419/686 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59921756; called by muse, mutect2, varscan2
- PRAMEF1 | c.1270C>A p.R424S | Missense Mutation (SNP) | VAF 103/882 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.052); catalogued as rs199886880; called by muse, mutect2, varscan2
- PRAMEF2 | c.1270C>A p.R424S | Missense Mutation (SNP) | VAF 66/998 reads (7%) | SIFT tolerated (0.49); PolyPhen benign (0.085); catalogued as rs140567467; called by muse, mutect2
- PTPRR | c.230G>C p.R77P | Missense Mutation (SNP) | VAF 250/778 reads (32%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.031); catalogued as COSV51727886; called by muse, mutect2, varscan2
- PXDNL | c.2869G>A p.G957R | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755663197, COSV62478360; called by muse, mutect2, varscan2
- RB1CC1 | c.1396G>T p.G466* | Nonsense Mutation (SNP) | VAF 208/745 reads (28%) | catalogued as COSV50278173; called by muse, mutect2, varscan2
- REG1A | c.240G>T p.E80D | Missense Mutation (SNP) | VAF 89/403 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.718); catalogued as COSV99286791; called by muse, mutect2, varscan2
- RHBDD2 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.181); catalogued as COSV50087164; called by muse, mutect2, varscan2
- RP1L1 | c.2492C>A p.T831K | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV66754112; called by muse, mutect2, varscan2
- RTL1 | c.1408G>T p.E470* | Nonsense Mutation (SNP) | VAF 57/145 reads (39%) | catalogued as rs371032871, COSV99062612; called by muse, mutect2, varscan2
- RYR2 | c.4985C>T p.S1662L | Missense Mutation (SNP) | VAF 158/433 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.203); catalogued as rs1294119002; called by muse, mutect2, varscan2
- SARAF | c.50G>T p.G17V | Missense Mutation (SNP) | VAF 75/208 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.067); catalogued as rs868302684, COSV56357212; called by muse, mutect2, varscan2
- SDK1 | c.899del p.G300Afs*17 | Frame Shift Del (DEL) | VAF 164/501 reads (33%) | catalogued as COSV101269768, COSV67363153, COSV67377139; called by mutect2, pindel, varscan2
- SEMA3D | c.229G>T p.E77* | Nonsense Mutation (SNP) | VAF 136/400 reads (34%) | catalogued as COSV99407381; called by muse, mutect2, varscan2
- SEMA5A | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 25/644 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs1305279801; called by muse, mutect2
- SETD2 | c.793G>A p.E265K | Missense Mutation (SNP) | VAF 51/232 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.084); catalogued as COSV57447391; called by muse, mutect2, varscan2
- SH2B2 | c.1594G>T p.D532Y | Missense Mutation (SNP) | VAF 112/331 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV100159180; called by muse, mutect2, varscan2
- SHB | c.1257C>A p.D419E | Missense Mutation (SNP) | VAF 117/311 reads (38%) | SIFT tolerated (0.49); PolyPhen benign (0.163); catalogued as COSV100891659; called by muse, mutect2, varscan2
- SIPA1L1 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 237/792 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as rs766603433; called by muse, mutect2, varscan2
- SLC18A3 | c.1235G>T p.R412L | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60328855; called by muse, mutect2, varscan2
- SLC22A25 | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.03); catalogued as rs1481791758; called by muse, varscan2
- SLC22A8 | c.885+5G>T | Splice Region (SNP) | VAF 80/213 reads (38%) | catalogued as rs753745636; called by muse, mutect2, varscan2
- SLC24A2 | c.789G>T p.W263C | Missense Mutation (SNP) | VAF 199/518 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99646764; called by muse, mutect2, varscan2
- SLC38A4 | c.795C>A p.N265K | Missense Mutation (SNP) | VAF 152/413 reads (37%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV56969287; called by muse, mutect2, varscan2
- SLC9A2 | c.1730C>A p.P577H | Missense Mutation (SNP) | VAF 127/402 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.942); catalogued as COSV99295692; called by muse, mutect2, varscan2
- SLF1 | c.1099G>C p.D367H | Missense Mutation (SNP) | VAF 101/206 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.599); catalogued as rs1379056991; called by muse, mutect2, varscan2
- SNTG1 | c.278C>A p.A93E | Missense Mutation (SNP) | VAF 223/608 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.285); catalogued as rs138942717, COSV52450226, COSV99383359; called by muse, mutect2, varscan2
- SPTBN5 | c.4661G>T p.G1554V | Missense Mutation (SNP) | VAF 54/139 reads (39%) | SIFT tolerated (0.45); PolyPhen benign (0.054); catalogued as rs1167848350; called by muse, mutect2, varscan2
- SUPT6H | c.907A>G p.I303V | Missense Mutation (SNP) | VAF 192/274 reads (70%) | SIFT tolerated (1); PolyPhen benign (0.026); catalogued as rs376077857; called by muse, mutect2, varscan2
- SYNE1 | c.18113C>T p.A6038V (on ENST00000367255 / NM_182961.4; = p.A5967V on NM_033071.3) | Missense Mutation (SNP) | VAF 37/622 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.053); catalogued as rs752183118; called by muse, mutect2
- TAS1R2 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 138/459 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV64746654; called by muse, mutect2, varscan2
- TDRD1 | c.3452T>A p.V1151D | Missense Mutation (SNP) | VAF 171/441 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV52591315; called by muse, mutect2, varscan2
- TENM2 | c.460C>A p.L154M | Missense Mutation (SNP) | VAF 364/656 reads (55%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV72852915; called by muse, mutect2, varscan2
- TFAP2D | c.509T>C p.L170P | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs1354392291; called by muse, mutect2, varscan2
- TMEM232 | c.981C>A p.D327E | Missense Mutation (SNP) | VAF 154/258 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as rs1274263163; called by muse, varscan2
- TMPRSS6 | c.306C>G p.F102L | Missense Mutation (SNP) | VAF 177/716 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1199090172; called by mutect2, varscan2
- TMTC1 | c.580G>T p.G194* (on ENST00000539277 / NM_001193451.2; = p.G86* on NM_175861.3) | Nonsense Mutation (SNP) | VAF 58/268 reads (22%) | catalogued as COSV55493569; called by muse, mutect2, varscan2
- TOR1AIP1 | c.739+1G>A p.X247_splice | Splice Site (SNP) | VAF 102/240 reads (43%) | catalogued as rs900977276; called by muse, mutect2, varscan2
- TRIOBP | c.3967G>A p.A1323T | Missense Mutation (SNP) | VAF 121/327 reads (37%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.012); catalogued as rs780288515; called by muse, mutect2, varscan2
- TUBGCP4 | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 112/446 reads (25%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs769525360; called by muse, mutect2, varscan2
- UGGT1 | c.77G>T p.G26V | Missense Mutation (SNP) | VAF 87/409 reads (21%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV52133711; called by muse, mutect2, varscan2
- USP19 | c.3071G>A p.R1024Q | Missense Mutation (SNP) | VAF 141/342 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.348); catalogued as rs757201117, COSV60046365; called by muse, mutect2, varscan2
- USP33 | c.107G>T p.R36L | Missense Mutation (SNP) | VAF 113/450 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.077); catalogued as COSV62468442; called by muse, mutect2, varscan2
- VEGFD | c.902G>A p.C301Y | Missense Mutation (SNP) | VAF 128/188 reads (68%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as COSV52909487; called by muse, mutect2, varscan2
- WDFY3 | c.10112C>A p.P3371H | Missense Mutation (SNP) | VAF 98/175 reads (56%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.014); catalogued as COSV55693591; called by muse, mutect2, varscan2
- WDR72 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 145/465 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.78); catalogued as COSV100854390; called by muse, mutect2, varscan2
- WSCD2 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 145/398 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as COSV54578902; called by muse, mutect2, varscan2
- WWOX | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 134/680 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.317); catalogued as rs1131691324, COSV68370583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- XCR1 | c.872G>T p.G291V | Missense Mutation (SNP) | VAF 100/469 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58571107; called by muse, mutect2, varscan2
- XIRP2 | c.8936C>G p.P2979R (on ENST00000628543; = p.P3154R on NM_152381.6) | Missense Mutation (SNP) | VAF 94/393 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.328); catalogued as COSV54694238; called by muse, mutect2, varscan2
- XPO6 | c.1919G>T p.S640I | Missense Mutation (SNP) | VAF 117/326 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as COSV58970352; called by muse, mutect2, varscan2
- ZNF217 | c.2075G>A p.G692E | Missense Mutation (SNP) | VAF 289/708 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.647); catalogued as COSV56600034; called by muse, mutect2, varscan2
- ZNF326 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 20/702 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV61034938; called by muse, mutect2
- ZNF407 | c.4764G>T p.R1588S | Missense Mutation (SNP) | VAF 64/241 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs765538100; called by muse, mutect2, varscan2
- ZNF879 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 198/315 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as rs914675767; called by muse, mutect2, varscan2
- ZSCAN1 | c.921C>A p.F307L | Missense Mutation (SNP) | VAF 141/240 reads (59%) | SIFT tolerated (0.69); PolyPhen benign (0.164); catalogued as COSV56605748, COSV56609005; called by muse, mutect2, varscan2
- ABCA13 | c.12923G>T p.W4308L | Missense Mutation (SNP) | VAF 203/582 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, varscan2
- ABCF3 | c.801G>T p.R267S | Missense Mutation (SNP) | VAF 31/151 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.232); called by muse, mutect2, varscan2
- AC011462.1 | c.532A>T p.S178C | Missense Mutation (SNP) | VAF 271/452 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- AC090150.2 | n.213G>T | Splice Region (SNP) | VAF 183/516 reads (35%) | called by muse, mutect2, varscan2
- AC100868.1 | c.78T>A p.H26Q | Missense Mutation (SNP) | VAF 55/167 reads (33%) | called by muse, mutect2, varscan2
- ACACB | c.5437G>A p.A1813T | Missense Mutation (SNP) | VAF 201/554 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- ACSM4 | c.283G>T p.G95C | Missense Mutation (SNP) | VAF 295/735 reads (40%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- ACTRT2 | c.944T>A p.L315H | Missense Mutation (SNP) | VAF 142/337 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ADAMTS2 | c.2542G>T p.V848F | Missense Mutation (SNP) | VAF 276/428 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.713); called by muse, mutect2, varscan2
- ADCY10 | c.2036C>A p.P679H | Missense Mutation (SNP) | VAF 215/557 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ADCY4 | c.1823G>T p.R608M | Missense Mutation (SNP) | VAF 134/344 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.277); called by muse, mutect2, varscan2
- ADGB | c.1180T>C p.S394P | Missense Mutation (SNP) | VAF 52/277 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AKAP12 | c.2303C>A p.P768Q | Missense Mutation (SNP) | VAF 110/243 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by mutect2, varscan2
- ANKRD17 | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 228/387 reads (59%) | called by muse, mutect2, varscan2
- ARHGAP1 | c.180G>T p.W60C | Missense Mutation (SNP) | VAF 132/520 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- ARHGAP12 | c.234G>T p.M78I | Missense Mutation (SNP) | VAF 183/516 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- ASTN1 | c.475G>A p.G159S | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ATP10D | c.3302T>A p.V1101D | Missense Mutation (SNP) | VAF 136/307 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- BACE2 | c.1348A>G p.T450A | Missense Mutation (SNP) | VAF 184/306 reads (60%) | SIFT tolerated (0.49); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- BCL7C | c.674G>C p.G225A | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BMERB1 | c.340G>T p.D114Y | Missense Mutation (SNP) | VAF 135/475 reads (28%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- BMPR1B | c.169A>T p.I57L | Missense Mutation (SNP) | VAF 668/1254 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.257); called by muse, varscan2
- BRPF1 | c.953G>T p.R318L | Missense Mutation (SNP) | VAF 35/179 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BTBD8 | c.739G>T p.V247F | Missense Mutation (SNP) | VAF 167/492 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.389); called by muse, mutect2, varscan2
- C4BPA | c.1273A>T p.I425F | Missense Mutation (SNP) | VAF 72/200 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- C4orf50 | c.535G>T p.E179* (on ENST00000324058; = p.E1411* on NM_001364689.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 122/221 reads (55%) | called by muse, mutect2, varscan2
- C4orf54 | c.4589C>T p.P1530L | Missense Mutation (SNP) | VAF 206/375 reads (55%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- CACNA1E | c.1043G>C p.G348A | Missense Mutation (SNP) | VAF 72/254 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARF | c.618G>T p.W206C | Missense Mutation (SNP) | VAF 38/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CARMIL1 | c.2786del p.L929Rfs*14 | Frame Shift Del (DEL) | VAF 104/309 reads (34%) | called by mutect2, pindel*, varscan2
- CARS2 | c.95G>T p.R32L | Missense Mutation (SNP) | VAF 81/130 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- CCDC88B | c.3457G>T p.G1153C | Missense Mutation (SNP) | VAF 36/81 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCDC88C | c.5978G>T p.G1993V | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CCN5 | c.116G>T p.C39F | Missense Mutation (SNP) | VAF 148/516 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD69 | c.103G>T p.G35W | Missense Mutation (SNP) | VAF 74/371 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CD86 | c.965G>T p.C322F (on ENST00000330540 / NM_175862.5; = p.C316F on NM_006889.4) | Missense Mutation (SNP) | VAF 94/519 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDC20B | c.1117G>T p.G373C | Missense Mutation (SNP) | VAF 211/803 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC27 | c.1381G>C p.G461R | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CDH18 | c.119A>T p.H40L | Missense Mutation (SNP) | VAF 352/735 reads (48%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- CEP162 | c.3924G>T p.E1308D | Missense Mutation (SNP) | VAF 62/340 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CFAP47 | c.518G>T p.G173V | Missense Mutation (SNP) | VAF 77/111 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CFAP47 | c.7061G>T p.G2354V | Missense Mutation (SNP) | VAF 93/142 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CGN | c.2558G>T p.R853L | Missense Mutation (SNP) | VAF 157/419 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- CILP2 | c.1979C>T p.P660L | Missense Mutation (SNP) | VAF 25/49 reads (51%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CLCN1 | c.122G>A p.G41D | Missense Mutation (SNP) | VAF 149/433 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- CLEC3A | c.82C>A p.Q28K (on ENST00000651443; = p.Q19K on NM_005752.6) | Missense Mutation (SNP) | VAF 97/488 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- CLEC4C | c.285C>A p.Y95* | Nonsense Mutation (SNP) | VAF 99/326 reads (30%) | called by muse, mutect2, varscan2
- CMTR2 | c.1663A>G p.I555V | Missense Mutation (SNP) | VAF 139/318 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL11A2 | c.3182G>T p.R1061L (on ENST00000341947 / NM_080680.3; = p.R954L on NM_080679.2) | Missense Mutation (SNP) | VAF 47/271 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- COL3A1 | c.3333C>A p.F1111L | Missense Mutation (SNP) | VAF 176/517 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL6A6 | c.4568C>A p.P1523H | Missense Mutation (SNP) | VAF 84/313 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.029); called by muse, varscan2
- CPE | c.1078G>C p.D360H | Missense Mutation (SNP) | VAF 139/287 reads (48%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CSMD2 | c.4581C>A p.S1527R | Missense Mutation (SNP) | VAF 184/521 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- CSMD3 | c.5959G>C p.E1987Q (on ENST00000297405 / NM_001363185.1; = p.E1883Q on NM_052900.3) | Missense Mutation (SNP) | VAF 343/863 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CSNK1A1 | c.699dup p.E234* | Frame Shift Ins (INS) | VAF 224/471 reads (48%) | called by mutect2, pindel, varscan2
- CSTF3 | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 85/421 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CTSC | c.832del p.S278Lfs*6 | Frame Shift Del (DEL) | VAF 352/1037 reads (34%) | called by mutect2, pindel, varscan2
- CYFIP1 | c.444G>T p.R148S | Missense Mutation (SNP) | VAF 125/300 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- CYFIP2 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 96/128 reads (75%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- CYP21A2 | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 56/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DCT | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 117/196 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DDB2 | c.130C>T p.P44S | Missense Mutation (SNP) | VAF 240/533 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- DDIAS | c.2125G>T p.A709S | Missense Mutation (SNP) | VAF 82/341 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- DEFB113 | c.109C>A p.L37I | Missense Mutation (SNP) | VAF 49/307 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.769); called by muse, mutect2, varscan2
- DELE1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 168/277 reads (61%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DENND2C | c.2040T>A p.H680Q (on ENST00000393274 / NM_001256404.2; = p.H623Q on NM_198459.4) | Missense Mutation (SNP) | VAF 119/428 reads (28%) | SIFT tolerated (0.36); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- DENND5A | c.2771A>G p.D924G | Missense Mutation (SNP) | VAF 31/437 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.752); called by muse, mutect2
- DHX8 | c.3067G>T p.D1023Y | Missense Mutation (SNP) | VAF 60/114 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- DLGAP2 | c.136G>T p.G46C | Missense Mutation (SNP) | VAF 158/468 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DMXL1 | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 218/333 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DNAH1 | c.4886G>T p.W1629L | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- DNAH7 | c.2058+1G>A p.X686_splice | Splice Site (SNP) | VAF 54/274 reads (20%) | called by muse, varscan2
- DOP1A | c.314dup p.L105Ffs*3 | Frame Shift Ins (INS) | VAF 26/157 reads (17%) | called by mutect2, varscan2
- DPP10 | c.1008G>T p.W336C | Missense Mutation (SNP) | VAF 76/401 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DSCAML1 | c.3922C>T p.L1308F (on ENST00000321322; = p.L1248F on NM_020693.4) | Missense Mutation (SNP) | VAF 57/163 reads (35%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- DUSP13 | c.298G>T p.D100Y | Missense Mutation (SNP) | VAF 120/421 reads (29%) | SIFT tolerated (0.48); PolyPhen benign (0.427); called by muse, mutect2, varscan2
- E2F6 | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 24/608 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- EHBP1 | c.105-1G>T p.X35_splice | Splice Site (SNP) | VAF 46/257 reads (18%) | called by mutect2, varscan2
- EIF2S3B | c.523G>T p.A175S | Missense Mutation (SNP) | VAF 256/841 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- ELOA | c.1332del p.K446Rfs*5 | Frame Shift Del (DEL) | VAF 184/591 reads (31%) | called by mutect2, pindel, varscan2
- EMILIN1 | c.11G>T p.R4L | Missense Mutation (SNP) | VAF 53/126 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- ENTPD4 | c.524A>T p.Y175F | Missense Mutation (SNP) | VAF 155/409 reads (38%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- EPRS1 | c.3002G>T p.G1001V | Missense Mutation (SNP) | VAF 102/319 reads (32%) | SIFT tolerated (0.15); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- FAM135B | c.553C>A p.P185T | Missense Mutation (SNP) | VAF 81/189 reads (43%) | SIFT tolerated (0.1); PolyPhen benign (0.159); called by muse, mutect2, varscan2
- FAM160B1 | c.1679A>G p.D560G | Missense Mutation (SNP) | VAF 166/514 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.042); called by muse, varscan2
- FAP | c.885G>T p.W295C | Missense Mutation (SNP) | VAF 123/273 reads (45%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); called by muse, mutect2, varscan2
- FDFT1 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 100/292 reads (34%) | SIFT tolerated (0.16); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- FLNC | c.5083G>T p.V1695F | Missense Mutation (SNP) | VAF 251/669 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.259G>T p.V87F | Missense Mutation (SNP) | VAF 124/343 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FRG2 | c.707C>A p.P236H | Missense Mutation (SNP) | VAF 124/626 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- FSIP2 | c.9116T>C p.M3039T | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- FSIP2 | c.12755A>C p.Q4252P | Missense Mutation (SNP) | VAF 62/163 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.302); called by muse, mutect2, varscan2
- GABRA5 | c.840G>A p.W280* | Nonsense Mutation (SNP) | VAF 97/246 reads (39%) | called by muse, mutect2, varscan2
- GABRA5 | c.1213G>T p.V405L | Missense Mutation (SNP) | VAF 232/630 reads (37%) | SIFT tolerated (0.83); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GFRA1 | c.1325G>T p.C442F | Missense Mutation (SNP) | VAF 241/744 reads (32%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- GLIPR1L2 | c.93_98del p.W32_L33del | In Frame Del (DEL) | VAF 65/583 reads (11%) | called by mutect2, pindel, varscan2
- GLP1R | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- GMNN | c.278A>G p.N93S | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- GRHL1 | c.1743-1G>T p.X581_splice | Splice Site (SNP) | VAF 83/187 reads (44%) | called by muse, mutect2, varscan2
- GRPR | c.587G>T p.C196F | Missense Mutation (SNP) | VAF 223/351 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GUCY1A2 | c.1603G>T p.A535S | Missense Mutation (SNP) | VAF 118/298 reads (40%) | SIFT tolerated (1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- GUCY2C | c.2348C>G p.T783R | Missense Mutation (SNP) | VAF 169/612 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GZMA | c.568G>C p.V190L | Missense Mutation (SNP) | VAF 202/446 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- HCFC1 | c.5978C>G p.P1993R | Missense Mutation (SNP) | VAF 28/36 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HCK | c.1375C>A p.P459T | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- HEATR5B | c.4126A>T p.S1376C | Missense Mutation (SNP) | VAF 22/146 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- HEPN1 | c.40G>T p.G14C | Missense Mutation (SNP) | VAF 105/334 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HMCN2 | c.10989C>G p.Y3663* | Nonsense Mutation (SNP) | VAF 60/115 reads (52%) | called by muse, mutect2, varscan2
- HMGA2 | c.164G>T p.S55I | Missense Mutation (SNP) | VAF 217/703 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- HMX2 | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 46/102 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- HOXD4 | c.575G>T p.C192F | Missense Mutation (SNP) | VAF 112/281 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- HRNR | c.5779G>T p.G1927W | Missense Mutation (SNP) | VAF 238/2364 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HTR3E | c.1237C>A p.H413N (on ENST00000415389 / NM_001256613.1; = p.H428N on NM_182589.2) | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- HYDIN | c.2451C>G p.I817M | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by mutect2, varscan2
- IER2 | c.373A>C p.S125R | Missense Mutation (SNP) | VAF 70/102 reads (69%) | SIFT deleterious (0.03); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- IFT74 | c.944A>T p.D315V | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IGFBP4 | c.38C>T p.A13V | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.92); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- IGHV3-35 | c.318G>T p.R106S | Missense Mutation (SNP) | VAF 83/219 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- IGKV1-12 | c.170G>A p.W57* | Nonsense Mutation (SNP) | VAF 104/1004 reads (10%) | called by muse, mutect2
- IGKV1D-33 | c.4G>T p.D2Y | Missense Mutation (SNP) | VAF 42/244 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- IGKV6D-21 | c.301G>A p.D101N | Missense Mutation (SNP) | VAF 88/227 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- IL17A | c.185G>A p.R62K | Missense Mutation (SNP) | VAF 60/461 reads (13%) | SIFT tolerated (0.33); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INSC | c.213G>T p.Q71H | Missense Mutation (SNP) | VAF 14/36 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.027); called by muse, varscan2
- INTS10 | c.197T>A p.M66K | Missense Mutation (SNP) | VAF 126/357 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.439); called by muse, mutect2, varscan2
- IQCB1 | c.712G>T p.A238S | Missense Mutation (SNP) | VAF 132/410 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- ITGA8 | c.2954C>A p.P985Q | Missense Mutation (SNP) | VAF 188/568 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- ITGA9 | c.2889G>T p.T963= | Splice Region (SNP) | VAF 177/491 reads (36%) | called by muse, mutect2, varscan2
- KAT8 | c.516+2T>G p.X172_splice | Splice Site (SNP) | VAF 83/156 reads (53%) | called by muse, mutect2, varscan2
- KCNH8 | c.1672G>T p.G558C | Missense Mutation (SNP) | VAF 125/539 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KCNIP2 | c.586A>T p.I196F (on ENST00000356640 / NM_173191.3; = p.I211F on NM_014591.5) | Missense Mutation (SNP) | VAF 98/324 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- KCNJ16 | c.461C>A p.S154Y | Missense Mutation (SNP) | VAF 112/406 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); called by muse, varscan2
- KCNQ4 | c.1328G>T p.G443V | Missense Mutation (SNP) | VAF 92/247 reads (37%) | SIFT tolerated (0.41); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- KDM4C | c.614G>T p.G205V | Missense Mutation (SNP) | VAF 54/129 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KDM5C | c.661dup p.E221Gfs*8 | Frame Shift Ins (INS) | VAF 277/489 reads (57%) | called by mutect2, pindel, varscan2
- KIAA0825 | c.1339G>T p.E447* | Nonsense Mutation (SNP) | VAF 212/402 reads (53%) | called by muse, mutect2, varscan2
- KIF4A | c.427A>T p.I143F | Missense Mutation (SNP) | VAF 99/133 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KLHL28 | c.442G>T p.G148C | Missense Mutation (SNP) | VAF 161/482 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KLK3 | c.50C>A p.A17D | Missense Mutation (SNP) | VAF 54/80 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); called by muse, mutect2
- KRT84 | c.425T>C p.V142A | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.679); called by muse, mutect2, varscan2
- KRTAP4-7 | c.247A>T p.S83C | Missense Mutation (SNP) | VAF 262/599 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, varscan2
- L3MBTL3 | c.1286G>T p.C429F | Missense Mutation (SNP) | VAF 69/425 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LACTBL1 | c.410A>T p.Q137L (on ENST00000618559; = p.Q182L on NM_001289974.2) | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.631); called by muse, mutect2
- LILRB4 | c.1028T>A p.V343E (on ENST00000391733 / NM_001278428.3; = p.V342E on NM_001278426.3) | Missense Mutation (SNP) | VAF 96/190 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, varscan2
- LPO | c.552del p.N185Tfs*19 | Frame Shift Del (DEL) | VAF 11/80 reads (14%) | called by mutect2, pindel, varscan2
- LRBA | c.1446G>T p.Q482H | Missense Mutation (SNP) | VAF 154/274 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by mutect2, varscan2
- LRRC7 | c.4431T>A p.S1477R (on ENST00000651989 / NM_001370785.2; = p.S1397R on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 189/482 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRRC9 | c.670C>T p.L224F | Missense Mutation (SNP) | VAF 92/260 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LY75 | c.1184A>T p.D395V | Missense Mutation (SNP) | VAF 119/319 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- MCRS1 | c.224G>T p.G75V | Missense Mutation (SNP) | VAF 74/172 reads (43%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MDN1 | c.4318G>T p.E1440* | Nonsense Mutation (SNP) | VAF 96/231 reads (42%) | called by muse, varscan2
- MFRP | c.326C>A p.P109H (on ENST00000449574; = p.P485H on NM_031433.4) | Missense Mutation (SNP) | VAF 223/553 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- MKI67 | c.9409G>T p.D3137Y | Missense Mutation (SNP) | VAF 266/641 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2, varscan2
- MMAB | c.574G>T p.A192S | Missense Mutation (SNP) | VAF 254/687 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MORC4 | c.2087G>T p.G696V | Missense Mutation (SNP) | VAF 191/287 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MPPED1 | c.875T>A p.M292K | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- MRC2 | c.2354G>T p.C785F | Missense Mutation (SNP) | VAF 126/316 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MRGPRD | c.63C>A p.S21R | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC16 | c.4774G>T p.E1592* | Nonsense Mutation (SNP) | VAF 109/203 reads (54%) | called by muse, mutect2, varscan2
- MUC17 | c.9845C>A p.P3282Q | Missense Mutation (SNP) | VAF 91/311 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MUC2 | c.2371dup p.E791Gfs*4 | Frame Shift Ins (INS) | VAF 55/210 reads (26%) | called by mutect2, pindel, varscan2
- MYO3A | c.3652G>T p.V1218F | Missense Mutation (SNP) | VAF 72/230 reads (31%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.021); called by muse, varscan2
- MYO6 | c.1264G>T p.A422S | Missense Mutation (SNP) | VAF 135/614 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MZF1 | c.2171T>C p.L724P | Missense Mutation (SNP) | VAF 117/219 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NBAS | c.3284G>T p.W1095L | Missense Mutation (SNP) | VAF 144/592 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NCKAP1L | c.2285C>A p.A762D | Missense Mutation (SNP) | VAF 258/748 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NEK10 | c.2996A>T p.N999I | Missense Mutation (SNP) | VAF 67/154 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NHSL1 | c.3236T>C p.M1079T | Missense Mutation (SNP) | VAF 60/281 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NIN | c.2725G>T p.V909F | Missense Mutation (SNP) | VAF 163/481 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- NKAIN4 | c.54+8G>T | Splice Region (SNP) | VAF 39/99 reads (39%) | called by muse, mutect2, varscan2
- NLRP1 | c.2876A>T p.D959V | Missense Mutation (SNP) | VAF 64/118 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- NLRP13 | c.2004C>A p.D668E | Missense Mutation (SNP) | VAF 175/308 reads (57%) | SIFT tolerated (0.47); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- NLRP14 | c.2716G>T p.D906Y | Missense Mutation (SNP) | VAF 132/527 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- NMNAT2 | c.445G>T p.A149S | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- NOX5 | c.1086G>T p.W362C | Missense Mutation (SNP) | VAF 117/290 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- NPAS4 | c.658C>A p.R220S | Missense Mutation (SNP) | VAF 105/241 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- NRK | c.2226G>T p.L742F | Missense Mutation (SNP) | VAF 62/98 reads (63%) | SIFT deleterious (0); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- NUP43 | c.490G>T p.V164L | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- OBSCN | c.17578C>A p.L5860M | Missense Mutation (SNP) | VAF 67/181 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OPRK1 | c.929C>A p.S310Y | Missense Mutation (SNP) | VAF 312/748 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- OR4C11 | c.887T>A p.M296K | Missense Mutation (SNP) | VAF 76/182 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.246); called by muse, varscan2
- OR4C12 | c.427G>T p.V143L | Missense Mutation (SNP) | VAF 97/470 reads (21%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- OR51M1 | c.418C>A p.H140N | Missense Mutation (SNP) | VAF 169/422 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- OR52K2 | c.918G>T p.L306F | Missense Mutation (SNP) | VAF 65/137 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.424); called by muse, mutect2
- OR5W2 | c.610G>T p.G204C | Missense Mutation (SNP) | VAF 114/274 reads (42%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR6B2 | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 55/246 reads (22%) | called by muse, mutect2, varscan2
- ORAI3 | c.489dup p.A164Cfs*2 | Frame Shift Ins (INS) | VAF 64/375 reads (17%) | called by mutect2, pindel, varscan2
- OSBPL6 | c.652G>T p.G218* | Nonsense Mutation (SNP) | VAF 132/348 reads (38%) | called by muse, mutect2, varscan2
- OTOF | c.5007G>C p.R1669S (on ENST00000272371 / NM_194248.3; = p.R902S on NM_004802.4) | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- OTOG | c.8246C>A p.P2749Q | Missense Mutation (SNP) | VAF 40/139 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PANX3 | c.796C>A p.L266M | Missense Mutation (SNP) | VAF 193/464 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- PAX3 | c.1140G>T p.M380I | Missense Mutation (SNP) | VAF 177/510 reads (35%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PELP1 | c.2503G>T p.A835S | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PEX14 | c.484A>G p.T162A | Missense Mutation (SNP) | VAF 330/807 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- PIGR | c.883G>T p.G295C | Missense Mutation (SNP) | VAF 69/185 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PIGT | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 70/266 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- PLCG2 | c.2675G>T p.R892M | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- PLEK2 | c.569A>G p.E190G | Missense Mutation (SNP) | VAF 71/241 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- PLEKHD1 | c.1427G>C p.R476P | Missense Mutation (SNP) | VAF 145/432 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- PLEKHG1 | c.1444A>C p.S482R | Missense Mutation (SNP) | VAF 164/432 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- POLRMT | c.2598G>T p.E866D | Missense Mutation (SNP) | VAF 197/298 reads (66%) | SIFT tolerated (0.09); PolyPhen benign (0.34); called by muse, mutect2, varscan2
- POTEE | c.2584A>T p.T862S | Missense Mutation (SNP) | VAF 176/562 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PPP1R2B | c.220C>A p.P74T | Missense Mutation (SNP) | VAF 511/813 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- PRCP | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRR14L | c.4169A>G p.Q1390R | Missense Mutation (SNP) | VAF 167/297 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PRR32 | c.587C>A p.P196Q | Missense Mutation (SNP) | VAF 263/372 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- PSTPIP2 | c.516G>T p.K172N | Missense Mutation (SNP) | VAF 93/266 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- PTCHD4 | c.2453A>G p.K818R | Missense Mutation (SNP) | VAF 118/274 reads (43%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- PTPN1 | c.1295A>G p.N432S | Missense Mutation (SNP) | VAF 117/327 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTPRD | c.3023G>C p.S1008T | Missense Mutation (SNP) | VAF 65/185 reads (35%) | SIFT tolerated (0.34); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PTPRZ1 | c.598G>T p.V200F | Missense Mutation (SNP) | VAF 116/420 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- RALGAPA1 | c.1840G>T p.G614C | Missense Mutation (SNP) | VAF 86/261 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- RB1CC1 | c.4105G>T p.E1369* | Nonsense Mutation (SNP) | VAF 160/350 reads (46%) | called by muse, mutect2, varscan2
- RELN | c.6324C>A p.Y2108* | Nonsense Mutation (SNP) | VAF 336/876 reads (38%) | called by muse, mutect2, varscan2
- RFPL3 | c.859A>C p.I287L (on ENST00000249007 / NM_001098535.1; = p.I258L on NM_006604.2) | Missense Mutation (SNP) | VAF 60/107 reads (56%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS18 | c.546G>T p.Q182H | Missense Mutation (SNP) | VAF 165/510 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- RIMBP2 | c.1583G>T p.G528V | Missense Mutation (SNP) | VAF 97/281 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RMDN3 | c.978_982dup p.L328Rfs*54 | Frame Shift Ins (INS) | VAF 118/556 reads (21%) | called by mutect2, varscan2
- RPL10A | c.527A>G p.D176G | Missense Mutation (SNP) | VAF 51/348 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- RPL10L | c.380C>G p.A127G | Missense Mutation (SNP) | VAF 324/905 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.443); called by muse, mutect2, varscan2
- RRAGB | c.1070A>G p.H357R (on ENST00000262850 / NM_016656.4; = p.H329R on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.284); called by muse, mutect2
- SACM1L | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 155/410 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- SALL3 | c.1360G>T p.G454W | Missense Mutation (SNP) | VAF 61/167 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SCAPER | c.2172G>T p.R724S | Missense Mutation (SNP) | VAF 51/331 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SDC2 | c.346G>T p.D116Y | Missense Mutation (SNP) | VAF 205/527 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- SEL1L | c.661G>T p.A221S | Missense Mutation (SNP) | VAF 150/441 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- SEMA3A | c.2108A>G p.Y703C | Missense Mutation (SNP) | VAF 203/549 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA5A | c.1715G>T p.S572I | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- SERPINH1 | c.706A>T p.M236L | Missense Mutation (SNP) | VAF 130/590 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- SETBP1 | c.1001A>T p.K334M | Missense Mutation (SNP) | VAF 222/726 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- SH2D4B | c.1162G>T p.D388Y | Missense Mutation (SNP) | VAF 103/314 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- SI | c.1455G>C p.W485C | Missense Mutation (SNP) | VAF 95/501 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SLC25A6 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 119/218 reads (55%) | called by muse, varscan2
- SLC6A15 | c.946G>T p.G316C | Missense Mutation (SNP) | VAF 154/561 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SNX19 | c.2356G>A p.D786N | Missense Mutation (SNP) | VAF 116/622 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SPATA31D1 | c.3484A>T p.T1162S | Missense Mutation (SNP) | VAF 209/335 reads (62%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- SPATS1 | c.767T>C p.F256S | Missense Mutation (SNP) | VAF 43/263 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SPEG | c.8687C>T p.S2896F | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- STIL | c.3103G>T p.A1035S | Missense Mutation (SNP) | VAF 79/201 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STK31 | c.2854T>A p.C952S | Missense Mutation (SNP) | VAF 332/625 reads (53%) | SIFT tolerated (0.76); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SULT1B1 | c.464C>A p.T155N | Missense Mutation (SNP) | VAF 206/353 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- SV2B | c.1730C>A p.A577E | Missense Mutation (SNP) | VAF 258/804 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- TAS2R14 | c.154del p.A52Qfs*10 | Frame Shift Del (DEL) | VAF 71/256 reads (28%) | called by mutect2, pindel, varscan2
- TBC1D15 | c.1939_1940insTGACGAAA p.N647Mfs*7 | Frame Shift Ins (INS) | VAF 102/474 reads (22%) | called by mutect2, varscan2
- TDRD12 | c.2127G>A p.M709I | Missense Mutation (SNP) | VAF 86/161 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- TLL2 | c.2989G>T p.G997C | Missense Mutation (SNP) | VAF 163/468 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM121 | c.4G>T p.V2L | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.758); called by muse, varscan2
- TMEM132C | c.13G>T p.G5C | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious, low confidence (0); called by mutect2, varscan2
- TMEM270 | c.317C>A p.T106N | Missense Mutation (SNP) | VAF 91/218 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- TMPRSS13 | c.158G>T p.R53L | Missense Mutation (SNP) | VAF 258/618 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- TMTC1 | c.581G>T p.G194V (on ENST00000539277 / NM_001193451.2; = p.G86V on NM_175861.3) | Missense Mutation (SNP) | VAF 58/271 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TNN | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 156/440 reads (35%) | called by muse, mutect2, varscan2
- TNNI3K | c.2389G>T p.E797* | Nonsense Mutation (SNP) | VAF 130/465 reads (28%) | called by muse, varscan2
- TOPBP1 | c.4174-2A>T p.X1392_splice | Splice Site (SNP) | VAF 64/166 reads (39%) | called by mutect2, varscan2
- TRAF1 | c.439G>T p.D147Y | Missense Mutation (SNP) | VAF 56/99 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.363); called by muse, mutect2, varscan2
- TRAPPC6B | c.149+1G>A p.X50_splice | Splice Site (SNP) | VAF 162/430 reads (38%) | called by muse, mutect2, varscan2
- TRBV23-1 | c.80C>A p.P27Q | Missense Mutation (SNP) | VAF 107/268 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TREH | c.122A>T p.Q41L | Missense Mutation (SNP) | VAF 114/401 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- TRIM10 | c.48C>A p.C16* | Nonsense Mutation (SNP) | VAF 72/167 reads (43%) | called by muse, mutect2, varscan2
- TRIM64B | c.293C>A p.T98N | Missense Mutation (SNP) | VAF 225/682 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- TRPM7 | c.4060G>T p.A1354S | Missense Mutation (SNP) | VAF 156/465 reads (34%) | SIFT tolerated, low confidence (0.21); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- TRPV5 | c.571G>T p.A191S | Missense Mutation (SNP) | VAF 126/363 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.696); called by muse, mutect2, varscan2
- TRUB1 | c.466G>T p.G156W | Missense Mutation (SNP) | VAF 268/845 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSEN15 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 174/454 reads (38%) | called by muse, mutect2, varscan2
- UGT2B10 | c.123C>G p.I41M | Missense Mutation (SNP) | VAF 190/344 reads (55%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- UNC5D | c.1764C>A p.P588= | Splice Region (SNP) | VAF 142/1306 reads (11%) | called by muse, mutect2, varscan2
- USP6 | c.3704A>G p.Q1235R | Missense Mutation (SNP) | VAF 270/482 reads (56%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.528); called by muse, mutect2, varscan2
- VAT1 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 113/247 reads (46%) | SIFT tolerated (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- VAV2 | c.2464G>C p.V822L (on ENST00000371850 / NM_001134398.2; = p.V783L on NM_003371.4) | Missense Mutation (SNP) | VAF 86/140 reads (61%) | SIFT tolerated (0.21); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- VWDE | c.1258G>T p.V420F | Missense Mutation (SNP) | VAF 142/290 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- WDR49 | c.1348G>T p.E450* (on ENST00000308378 / NM_001366158.1; = p.E791* on NM_001348951.2 and 2 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 20/112 reads (18%) | called by muse, mutect2
- WDR64 | c.2128C>A p.L710I | Missense Mutation (SNP) | VAF 124/440 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- XKR7 | c.1086G>T p.M362I | Missense Mutation (SNP) | VAF 137/404 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- YIPF5 | c.345del p.V116* | Frame Shift Del (DEL) | VAF 103/599 reads (17%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.331C>T p.H111Y (on ENST00000474710 / NM_001164342.2; = p.H38Y on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 93/251 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- ZC3H6 | c.2327C>T p.P776L | Missense Mutation (SNP) | VAF 85/335 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ZHX2 | c.532G>T p.G178W | Missense Mutation (SNP) | VAF 219/489 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZHX2 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 215/481 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- ZNF257 | c.1675A>C p.T559P | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ZNF28 | c.32G>T p.R11M | Missense Mutation (SNP) | VAF 138/261 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- ZNF292 | c.1367G>A p.C456Y | Missense Mutation (SNP) | VAF 96/421 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF454 | c.830G>T p.C277F | Missense Mutation (SNP) | VAF 267/447 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF486 | c.452G>T p.S151I | Missense Mutation (SNP) | VAF 146/256 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ZNF587B | c.1079A>T p.E360V | Missense Mutation (SNP) | VAF 68/117 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ZNF648 | c.1159C>A p.L387M | Missense Mutation (SNP) | VAF 73/186 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- ZNF687 | c.2863G>T p.G955C | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ZNF729 | c.492T>A p.H164Q | Missense Mutation (SNP) | VAF 82/140 reads (59%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- ZNF845 | c.2128A>T p.K710* | Nonsense Mutation (SNP) | VAF 153/264 reads (58%) | called by muse, mutect2, varscan2
- ZNF850 | c.2766G>C p.E922D | Missense Mutation (SNP) | VAF 108/184 reads (59%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, mutect2, varscan2
- A4GNT | c.855T>C p.Y285= | Silent (SNP) | VAF 236/508 reads (46%) | catalogued as rs762115616; called by muse, mutect2, varscan2
- ABCA13 | c.12627C>A p.A4209= | Silent (SNP) | VAF 54/155 reads (35%) | catalogued as COSV68948248; called by muse, mutect2, varscan2
- ADAM8 | c.2424G>A p.L808= | Silent (SNP) | VAF 29/142 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS12 | c.3930C>T p.N1310= | Silent (SNP) | VAF 108/259 reads (42%) | catalogued as rs141717162; called by muse, mutect2, varscan2
- ANKRD26 | c.3363A>G p.K1121= | Silent (SNP) | VAF 72/219 reads (33%) | called by muse, mutect2, varscan2
- APOM | c.99C>T p.G33= | Silent (SNP) | VAF 115/235 reads (49%) | catalogued as rs535853455, COSV52997076; called by muse, mutect2, varscan2
- BEGAIN | c.1182C>A p.P394= | Silent (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2, varscan2
- CACNA1A | c.3414C>G p.P1138= | Silent (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- CALCRL | c.618C>A p.A206= | Silent (SNP) | VAF 81/215 reads (38%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.4326A>T p.T1442= | Silent (SNP) | VAF 139/244 reads (57%) | called by muse, mutect2, varscan2
- CATSPERE | c.207G>A p.L69= | Silent (SNP) | VAF 169/548 reads (31%) | catalogued as rs781171580; called by muse, mutect2, varscan2
- CAV3 | c.63G>A p.E21= | Silent (SNP) | VAF 234/605 reads (39%) | catalogued as rs1417709772; called by muse, mutect2, varscan2
- CBY2 | c.768G>T p.A256= | Silent (SNP) | VAF 25/37 reads (68%) | catalogued as COSV60120251; called by muse, mutect2, varscan2
- CDH4 | c.702C>A p.P234= | Silent (SNP) | VAF 44/138 reads (32%) | called by muse, mutect2, varscan2
- CELF4 | c.183C>A p.I61= | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as rs1255925367, COSV58455230; called by muse, mutect2, varscan2
- CHRNA2 | c.978G>C p.P326= | Silent (SNP) | VAF 304/835 reads (36%) | catalogued as COSV53556104; called by muse, mutect2, varscan2
- CNTN3 | c.798G>A p.G266= | Silent (SNP) | VAF 49/197 reads (25%) | called by muse, mutect2, varscan2
- COL19A1 | c.2181G>T p.R727= | Silent (SNP) | VAF 66/313 reads (21%) | called by muse, mutect2, varscan2
- COL22A1 | c.261C>A p.T87= | Silent (SNP) | VAF 85/195 reads (44%) | catalogued as COSV57354770; called by muse, mutect2, varscan2
- COL6A6 | c.1431C>A p.A477= | Silent (SNP) | VAF 59/284 reads (21%) | called by muse, mutect2, varscan2
- CPED1 | c.2247C>A p.P749= | Silent (SNP) | VAF 265/842 reads (31%) | called by muse, mutect2, varscan2
- CPLANE1 | c.9462G>T p.G3154= | Silent (SNP) | VAF 48/224 reads (21%) | called by muse, mutect2, varscan2
- CSMD1 | c.6678G>T p.A2226= (on ENST00000520002; = p.A2225= on NM_033225.6) | Silent (SNP) | VAF 139/458 reads (30%) | catalogued as COSV59338632, COSV59390505; called by muse, mutect2, varscan2
- CTU1 | c.987G>T p.T329= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1472236552; called by muse, mutect2, varscan2
- DDX60 | c.4059C>T p.S1353= | Silent (SNP) | VAF 294/546 reads (54%) | called by muse, mutect2, varscan2
- DMD | c.1641A>G p.T547= | Silent (SNP) | VAF 195/298 reads (65%) | catalogued as rs1394724423; called by muse, mutect2, varscan2
- ECRG4 | c.384A>C p.A128= | Silent (SNP) | VAF 69/314 reads (22%) | called by muse, mutect2, varscan2
- ENTR1 | c.39G>C p.L13= | Silent (SNP) | VAF 60/97 reads (62%) | called by muse, mutect2, varscan2
- EPHB3 | c.672G>A p.E224= | Silent (SNP) | VAF 43/89 reads (48%) | called by muse, mutect2, varscan2
- FNDC7 | c.612T>A p.P204= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as COSV54751140; called by muse, mutect2
- GALNT14 | c.246G>T p.R82= | Silent (SNP) | VAF 97/275 reads (35%) | called by muse, mutect2, varscan2
- GATAD2A | c.24A>G p.T8= | Silent (SNP) | VAF 122/194 reads (63%) | catalogued as rs771221511; called by muse, mutect2
- GCDH | c.522G>T p.L174= | Silent (SNP) | VAF 193/304 reads (63%) | called by muse, mutect2, varscan2
- GMPR | c.801C>T p.Y267= | Silent (SNP) | VAF 110/273 reads (40%) | catalogued as rs564026252; called by muse, mutect2, varscan2
- GTF3C2 | c.612A>T p.T204= | Silent (SNP) | VAF 26/125 reads (21%) | called by muse, mutect2, varscan2
- GUCY2F | c.1509C>A p.P503= | Silent (SNP) | VAF 98/151 reads (65%) | called by muse, mutect2, varscan2
- H1-5 | c.414G>T p.T138= | Silent (SNP) | VAF 82/469 reads (17%) | catalogued as COSV100138090; called by muse, mutect2, varscan2
- HCN4 | c.903G>T p.V301= | Silent (SNP) | VAF 104/316 reads (33%) | called by muse, mutect2, varscan2
- HEPACAM2 | c.582C>A p.T194= (on ENST00000394468 / NM_001039372.4; = p.T182= on NM_198151.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 317/938 reads (34%) | called by mutect2, varscan2
- HMGCS2 | c.690G>T p.L230= | Silent (SNP) | VAF 323/965 reads (33%) | catalogued as COSV65567050; called by muse, mutect2, varscan2
- HOXB3 | c.1143C>A p.S381= | Silent (SNP) | VAF 52/130 reads (40%) | catalogued as COSV100290623, COSV57486410; called by muse, mutect2, varscan2
- HPD | c.537G>A p.E179= | Silent (SNP) | VAF 148/471 reads (31%) | called by muse, mutect2, varscan2
- HTR7 | c.1425C>G p.V475= (on ENST00000336152 / NM_019859.4; = p.H443D on NM_000872.5) | Silent (SNP) | VAF 108/414 reads (26%) | called by muse, mutect2, varscan2
- IL22RA1 | c.219G>T p.R73= | Silent (SNP) | VAF 91/202 reads (45%) | catalogued as COSV54630371, COSV99582863; called by muse, mutect2, varscan2
- IL2RB | c.585G>A p.L195= | Silent (SNP) | VAF 81/286 reads (28%) | called by muse, mutect2, varscan2
- KCNJ16 | c.462C>T p.S154= | Silent (SNP) | VAF 118/412 reads (29%) | called by muse, mutect2, varscan2
- KCNT2 | c.3318A>T p.P1106= | Silent (SNP) | VAF 151/419 reads (36%) | catalogued as COSV99654912; called by muse, mutect2, varscan2
- KCNU1 | c.1605T>C p.A535= | Silent (SNP) | VAF 136/1642 reads (8%) | called by muse, mutect2
- KRT82 | c.1191C>A p.A397= | Silent (SNP) | VAF 170/445 reads (38%) | called by muse, mutect2, varscan2
- KYNU | c.705C>A p.A235= | Silent (SNP) | VAF 113/571 reads (20%) | called by muse, mutect2, varscan2
- LAMB1 | c.3499C>A p.R1167= | Silent (SNP) | VAF 242/655 reads (37%) | catalogued as COSV55961656; called by muse, mutect2, varscan2
- LOXHD1 | c.3567G>T p.A1189= | Silent (SNP) | VAF 105/435 reads (24%) | called by muse, mutect2, varscan2
- MC3R | c.687G>C p.G229= | Silent (SNP) | VAF 151/321 reads (47%) | called by muse, mutect2, varscan2
- MED13L | c.3180C>T p.P1060= | Silent (SNP) | VAF 67/174 reads (39%) | called by muse, mutect2, varscan2
- MLXIP | c.2589G>T p.T863= | Silent (SNP) | VAF 102/242 reads (42%) | catalogued as COSV100038326; called by muse, mutect2, varscan2
- NCAM1 | c.2178C>T p.G726= (on ENST00000316851 / NM_181351.5; = p.G716= on NM_000615.7) | Silent (SNP) | VAF 91/453 reads (20%) | called by muse, mutect2, varscan2
- NCKIPSD | c.927C>T p.P309= | Silent (SNP) | VAF 46/174 reads (26%) | called by muse, varscan2
- NKX3-2 | c.525C>G p.S175= | Silent (SNP) | VAF 71/125 reads (57%) | catalogued as rs751517920; called by muse, mutect2, varscan2
- NKX3-2 | c.378C>T p.G126= | Silent (SNP) | VAF 11/22 reads (50%) | called by muse, mutect2, varscan2
- NLRP3 | c.462C>G p.A154= | Silent (SNP) | VAF 250/663 reads (38%) | catalogued as COSV60229414; called by muse, mutect2, varscan2
- NOMO1 | c.3471A>T p.A1157= | Silent (SNP) | VAF 86/1266 reads (7%) | called by muse, mutect2
- NTRK3 | c.975G>T p.V325= | Silent (SNP) | VAF 76/363 reads (21%) | catalogued as COSV100446142; called by muse, mutect2, varscan2
- NUTM1 | c.1056G>A p.Q352= | Silent (SNP) | VAF 130/618 reads (21%) | called by muse, varscan2
- OR2L2 | c.396C>A p.P132= | Silent (SNP) | VAF 238/710 reads (34%) | catalogued as COSV63550606; called by mutect2, varscan2
- OR2M3 | c.453G>A p.L151= | Silent (SNP) | VAF 165/514 reads (32%) | catalogued as rs757212778; called by muse, mutect2, varscan2
- OR4C11 | c.558C>A p.A186= | Silent (SNP) | VAF 124/300 reads (41%) | called by muse, mutect2, varscan2
- OTOG | c.2988G>T p.T996= | Silent (SNP) | VAF 137/349 reads (39%) | catalogued as COSV61131689; called by muse, mutect2, varscan2
- PADI6 | c.768T>A p.T256= | Silent (SNP) | VAF 65/250 reads (26%) | called by muse, mutect2, varscan2
- PCDH17 | c.2232C>A p.I744= | Silent (SNP) | VAF 222/376 reads (59%) | catalogued as rs769907429, COSV100932226, COSV64978049; called by muse, mutect2, varscan2
- PCDH7 | c.1563G>T p.L521= | Silent (SNP) | VAF 186/318 reads (58%) | catalogued as rs1203750284, COSV62340159; called by muse, mutect2, varscan2
- PCDHGA6 | c.1917G>A p.K639= | Silent (SNP) | VAF 221/334 reads (66%) | catalogued as rs771269314, COSV53933770; called by muse, mutect2, varscan2
- PHYHIP | c.585C>A p.P195= | Silent (SNP) | VAF 50/158 reads (32%) | catalogued as COSV100395127; called by muse, mutect2, varscan2
- PIK3R6 | c.1449C>A p.R483= | Silent (SNP) | VAF 68/113 reads (60%) | called by muse, mutect2, varscan2
- PMS1 | c.909A>T p.T303= | Silent (SNP) | VAF 117/615 reads (19%) | called by muse, mutect2, varscan2
- PNOC | c.27G>A p.L9= | Silent (SNP) | VAF 18/404 reads (4%) | called by muse, mutect2
- POGLUT2 | c.93G>A p.K31= | Silent (SNP) | VAF 75/149 reads (50%) | catalogued as COSV99958566; called by muse, mutect2, varscan2
- POLE | c.3501G>T p.L1167= | Silent (SNP) | VAF 68/246 reads (28%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.597A>T p.G199= | Silent (SNP) | VAF 115/421 reads (27%) | called by muse, mutect2, varscan2
- QKI | c.702G>T p.P234= | Silent (SNP) | VAF 143/339 reads (42%) | catalogued as rs761669902; called by muse, mutect2, varscan2
- RYR2 | c.12879C>A p.T4293= | Silent (SNP) | VAF 227/596 reads (38%) | called by muse, mutect2, varscan2
- SAMD11 | c.1008G>T p.A336= | Silent (SNP) | VAF 40/93 reads (43%) | called by muse, mutect2, varscan2
- SDC3 | c.1251C>T p.G417= | Silent (SNP) | VAF 131/395 reads (33%) | called by muse, mutect2, varscan2
- SEC16B | c.1476G>A p.T492= | Silent (SNP) | VAF 37/568 reads (7%) | catalogued as rs747682859, COSV57623246; called by muse, mutect2
- SH3GL1 | c.345G>T p.L115= | Silent (SNP) | VAF 76/128 reads (59%) | called by muse, mutect2, varscan2
- SLC11A1 | c.300C>T p.T100= | Silent (SNP) | VAF 103/274 reads (38%) | catalogued as rs749459278; called by muse, mutect2, varscan2
- SLC2A3 | c.234C>A p.S78= | Silent (SNP) | VAF 133/386 reads (34%) | called by muse, mutect2, varscan2
- SLC37A2 | c.870G>T p.G290= | Silent (SNP) | VAF 21/77 reads (27%) | called by muse, mutect2, varscan2
- SLC8A1 | c.1437C>T p.I479= | Silent (SNP) | VAF 51/198 reads (26%) | catalogued as COSV60476953, COSV60481266; called by muse, mutect2, varscan2
- SLC9A6 | c.1116G>T p.T372= | Silent (SNP) | VAF 200/313 reads (64%) | catalogued as COSV65788280; called by muse, mutect2, varscan2
- SPANXC | c.240C>A p.L80= | Silent (SNP) | VAF 84/160 reads (53%) | called by muse, mutect2, varscan2
- SPTA1 | c.5307C>A p.I1769= | Silent (SNP) | VAF 201/634 reads (32%) | called by muse, mutect2
- STYXL2 | c.2574G>A p.K858= | Silent (SNP) | VAF 165/425 reads (39%) | called by muse, mutect2, varscan2
- SYTL2 | c.2394G>T p.V798= (on ENST00000528231 / NM_001162951.2; = p.V774= on NM_032943.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 144/444 reads (32%) | called by muse, mutect2, varscan2
- TAS1R1 | c.933G>C p.G311= | Silent (SNP) | VAF 16/37 reads (43%) | catalogued as COSV100039468; called by muse, mutect2, varscan2
- TAS1R2 | c.561C>G p.A187= | Silent (SNP) | VAF 42/102 reads (41%) | called by muse, mutect2, varscan2
- TENM2 | c.459C>A p.T153= | Silent (SNP) | VAF 361/653 reads (55%) | catalogued as COSV101595489; called by muse, mutect2, varscan2
- TFAP2D | c.510G>C p.L170= | Silent (SNP) | VAF 36/73 reads (49%) | called by muse, mutect2
- TFIP11 | c.384C>T p.S128= | Silent (SNP) | VAF 37/157 reads (24%) | called by muse, mutect2, varscan2
- TMEM151A | c.85C>T p.L29= | Silent (SNP) | VAF 89/192 reads (46%) | catalogued as rs1442612881; called by muse, mutect2, varscan2
- TMEM44 | c.903C>T p.G301= (on ENST00000392432 / NM_001166305.2; = p.G254= on NM_138399.5) | Silent (SNP) | VAF 28/56 reads (50%) | catalogued as rs1435742554; called by muse, mutect2, varscan2
- TRPM2 | c.591G>T p.V197= | Silent (SNP) | VAF 24/37 reads (65%) | called by muse, mutect2, varscan2
- TSHZ1 | c.1998G>T p.L666= (on ENST00000580243 / NM_001308210.2; = p.L621= on NM_005786.6) | Silent (SNP) | VAF 50/202 reads (25%) | called by mutect2, varscan2
- TUBB8B | c.330G>T p.A110= | Silent (SNP) | VAF 190/918 reads (21%) | catalogued as rs773463391; called by muse, varscan2
- UPK3A | c.225C>T p.A75= | Silent (SNP) | VAF 171/430 reads (40%) | called by muse, mutect2, varscan2
- USP17L7 | c.75A>T p.L25= | Silent (SNP) | VAF 328/927 reads (35%) | catalogued as rs774018125; called by muse, mutect2, varscan2
- VGLL3 | c.138G>T p.A46= | Silent (SNP) | VAF 24/107 reads (22%) | catalogued as COSV67353580; called by muse, varscan2
- VWA3A | c.2757G>A p.T919= | Silent (SNP) | VAF 46/229 reads (20%) | catalogued as rs750625227, COSV100241393; called by muse, mutect2, varscan2
- ZDHHC11 | c.870A>G p.P290= | Silent (SNP) | VAF 90/830 reads (11%) | called by muse, mutect2, varscan2
- ZDHHC11B | c.870A>G p.P290= | Silent (SNP) | VAF 120/259 reads (46%) | called by muse, mutect2, varscan2
- ZNF215 | c.1125A>C p.T375= | Silent (SNP) | VAF 101/249 reads (41%) | called by muse, mutect2, varscan2
- ZNF497 | c.729G>T p.A243= | Silent (SNP) | VAF 36/67 reads (54%) | catalogued as rs745311435; called by muse, mutect2, varscan2
- AC083899.1 | n.3456C>A | RNA (SNP) | VAF 96/768 reads (13%) | called by muse, varscan2
- AC138749.1 | n.583G>T | RNA (SNP) | VAF 7/16 reads (44%) | called by mutect2, varscan2
- ACAA2 | chr18:49814283 C>T | 5'Flank (SNP) | VAF 69/214 reads (32%) | called by muse, mutect2, varscan2
- ADTRP | c.154-1702G>T | Intron (SNP) | VAF 61/405 reads (15%) | called by muse, mutect2, varscan2
- AL772337.1 | n.858-111C>A | Intron (SNP) | VAF 68/114 reads (60%) | called by muse, varscan2
- ALG9 | c.1713-1959G>T | Intron (SNP) | VAF 96/361 reads (27%) | called by muse, mutect2, varscan2
- AP001007.2 | n.413C>A | RNA (SNP) | VAF 114/531 reads (21%) | called by muse, mutect2, varscan2
- ARHGEF4 | chr2:130915732 C>T | 5'Flank (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- ASTN2 | c.*311G>T | 3'UTR (SNP) | VAF 275/477 reads (58%) | called by muse, mutect2, varscan2
- ATP5F1C | c.-4_-1del | 5'UTR (DEL) | VAF 80/433 reads (18%) | called by mutect2, pindel, varscan2
- BMS1P15 | n.347T>A | RNA (SNP) | VAF 156/498 reads (31%) | called by muse, mutect2, varscan2
- C10orf95 | chr10:102454195 A>G | 5'Flank (SNP) | VAF 146/392 reads (37%) | called by muse, varscan2
- C7orf50 | c.*22C>T | 3'UTR (SNP) | VAF 18/39 reads (46%) | called by muse, mutect2, varscan2
- CACNA1C | c.1391-2479G>T | Intron (SNP) | VAF 129/465 reads (28%) | called by muse, mutect2, varscan2
- CALY | c.246+61G>T | Intron (SNP) | VAF 74/181 reads (41%) | called by muse, mutect2, varscan2
- CARD9 | c.952-12C>T | Intron (SNP) | VAF 95/146 reads (65%) | catalogued as rs541356831; called by muse, mutect2, varscan2
- CCDC74A | c.295+444C>A | Intron (SNP) | VAF 71/333 reads (21%) | called by muse, mutect2, varscan2
- CD55 | c.101-110G>T | Intron (SNP) | VAF 70/277 reads (25%) | called by muse, mutect2, varscan2
- CFAP54 | c.4547+796G>A | Intron (SNP) | VAF 69/196 reads (35%) | called by muse, mutect2, varscan2
- CHRNA4 | c.*2547C>A | 3'UTR (SNP) | VAF 297/620 reads (48%) | called by muse, mutect2, varscan2
- CLVS1 | c.-152+4267del | Intron (DEL) | VAF 96/416 reads (23%) | called by mutect2, pindel, varscan2
- CNTN2 | c.2126-10C>A | Intron (SNP) | VAF 77/205 reads (38%) | called by muse, mutect2, varscan2
- CNTNAP4 | c.86-22G>T | Intron (SNP) | VAF 113/576 reads (20%) | called by muse, mutect2, varscan2
- COG4 | c.1062-16G>T | Intron (SNP) | VAF 182/395 reads (46%) | catalogued as rs1333299159; called by muse, varscan2
- COG4 | c.1003-59A>C | Intron (SNP) | VAF 197/441 reads (45%) | called by muse, mutect2, varscan2
- COPS8 | c.149+327A>G | Intron (SNP) | VAF 20/110 reads (18%) | called by muse, mutect2
- CYP11B1 | c.239+142G>T | Intron (SNP) | VAF 106/345 reads (31%) | catalogued as COSV52830862; called by muse, mutect2, varscan2
- CYP2B7P | n.431G>T | RNA (SNP) | VAF 232/395 reads (59%) | called by muse, mutect2, varscan2
- DMWD | c.*153A>G | 3'UTR (SNP) | VAF 16/31 reads (52%) | catalogued as rs775069249; called by muse, mutect2, varscan2
- DNAH14 | c.3052-23039C>T | Intron (SNP) | VAF 126/381 reads (33%) | called by muse, mutect2, varscan2
- DNAI4 | c.170+5588G>T | Intron (SNP) | VAF 52/132 reads (39%) | called by muse, mutect2, varscan2
- FHL2 | chr2:105399063 C>A | 5'Flank (SNP) | VAF 56/152 reads (37%) | called by muse, mutect2, varscan2
- FLJ40288 | n.771G>T | RNA (SNP) | VAF 107/292 reads (37%) | called by muse, mutect2, varscan2
- GLT1D1 | c.-40G>T | 5'UTR (SNP) | VAF 5/16 reads (31%) | called by muse, mutect2, varscan2
- HDAC9 | c.-158G>T | 5'UTR (SNP) | VAF 341/590 reads (58%) | called by muse, mutect2, varscan2
- HDGFL2 | c.1328+517G>T | Intron (SNP) | VAF 19/32 reads (59%) | called by muse, mutect2, varscan2
- HOXC11 | c.*139C>T | 3'UTR (SNP) | VAF 45/243 reads (19%) | called by muse, mutect2, varscan2
- IGFBP3 | c.-22G>T | 5'UTR (SNP) | VAF 101/256 reads (39%) | called by muse, mutect2, varscan2
- IGHMBP2 | c.*24G>A | 3'UTR (SNP) | VAF 37/68 reads (54%) | catalogued as rs377522095; called by muse, mutect2, varscan2
- ITGAM | c.3390+11C>T | Intron (SNP) | VAF 32/140 reads (23%) | called by muse, mutect2, varscan2
- KAT5 | c.79+147C>G | Intron (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- KIF7 | c.329-86C>A | Intron (SNP) | VAF 44/125 reads (35%) | called by muse, mutect2, varscan2
- LINC00529 | n.199G>T | RNA (SNP) | VAF 56/223 reads (25%) | called by muse, mutect2, varscan2
- LINC00692 | n.760A>T | RNA (SNP) | VAF 108/560 reads (19%) | called by muse, mutect2, varscan2
- LRBA | c.6363+8803A>T | Intron (SNP) | VAF 185/352 reads (53%) | called by muse, mutect2, varscan2
- MGAM | c.4618+5604G>T | Intron (SNP) | VAF 222/566 reads (39%) | called by muse, mutect2, varscan2
- MIR4739 | chr17:79707312 C>A | 5'Flank (SNP) | VAF 36/120 reads (30%) | called by muse, mutect2
- MIR891A | n.23G>C | RNA (SNP) | VAF 72/106 reads (68%) | called by muse, mutect2, varscan2
- MPPED1 | c.-8G>C | 5'UTR (SNP) | VAF 75/149 reads (50%) | called by muse, mutect2, varscan2
- MSC | c.-169C>A | 5'UTR (SNP) | VAF 146/359 reads (41%) | catalogued as rs1414879700; called by muse, mutect2, varscan2
- MUC19 | n.5397G>T | RNA (SNP) | VAF 143/358 reads (40%) | called by muse, mutect2, varscan2
- NOTCH3 | c.3328-27G>T | Intron (SNP) | VAF 135/232 reads (58%) | called by muse, mutect2, varscan2
- OFCC1 | n.2441C>A | RNA (SNP) | VAF 53/127 reads (42%) | called by muse, mutect2, varscan2
- PLEKHB2 | c.-114G>T | 5'UTR (SNP) | VAF 46/192 reads (24%) | called by muse, mutect2, varscan2
- PPEF2 | c.1757-128A>G | Intron (SNP) | VAF 112/622 reads (18%) | called by muse, mutect2, varscan2
- PPP1R18 | c.*177C>T | 3'UTR (SNP) | VAF 122/248 reads (49%) | catalogued as rs748445662; called by muse, mutect2, varscan2
- PTPRQ | c.19+1138C>A | Intron (SNP) | VAF 137/539 reads (25%) | called by muse, mutect2, varscan2
- RAB35 | c.*411G>A | 3'UTR (SNP) | VAF 123/286 reads (43%) | catalogued as rs1449041562; called by muse, mutect2, varscan2
- REXO2 | c.-24G>T | 5'UTR (SNP) | VAF 48/164 reads (29%) | called by muse, mutect2, varscan2
- RPAP1 | c.3795+125G>T | Intron (SNP) | VAF 31/69 reads (45%) | called by muse, mutect2, varscan2
- RPL13AP20 | n.66C>T | RNA (SNP) | VAF 254/619 reads (41%) | catalogued as rs560144255; called by muse, mutect2, varscan2
- RPS13 | c.423-195C>T | Intron (SNP) | VAF 83/328 reads (25%) | called by muse, mutect2, varscan2
- SELENON | c.1388-289G>T | Intron (SNP) | VAF 24/60 reads (40%) | called by muse, varscan2
- SINHCAF | c.-21+824G>T | Intron (SNP) | VAF 71/273 reads (26%) | called by muse, mutect2, varscan2
- SP8 | chr7:20784262 G>T | 3'Flank (SNP) | VAF 8/18 reads (44%) | called by muse, mutect2, varscan2
- TPO | c.2387-161G>A | Intron (SNP) | VAF 46/184 reads (25%) | catalogued as rs187044168; called by muse, mutect2, varscan2
- TRIM49C | c.-1C>A | 5'UTR (SNP) | VAF 22/68 reads (32%) | called by mutect2, varscan2
- TSC2 | c.337-45G>T | Intron (SNP) | VAF 63/257 reads (25%) | called by muse, mutect2, varscan2
- TTC39B | c.-16G>A | 5'UTR (SNP) | VAF 41/137 reads (30%) | called by muse, mutect2, varscan2
- TTLL7 | c.-208G>T | 5'UTR (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- TUBB7P | n.198G>T | RNA (SNP) | VAF 174/334 reads (52%) | called by muse, mutect2, varscan2
- VSTM2A | c.634+3890G>T | Intron (SNP) | VAF 164/441 reads (37%) | called by muse, mutect2, varscan2
- XIST | n.9547C>A | RNA (SNP) | VAF 117/170 reads (69%) | called by muse, mutect2, varscan2
